Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A737, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A737-01A (Primary Tumor).

ICD-O-3
Oligoastrocytoma, grade II 9400/3
Site Brain, supratentorial NOS C71.0
JW 8/15/13

Case #

Patient: Age (years): Gender:

Clinical diagnosis: Brain tumor

Date of procurement:

Sample:

Gross description:

The received material presented by pink - white soft-elastic pieces from right frontal lobe.

Microscopic description:

Received material is represented by brain tissue consistent with oligoastrocytoma. Ki67 5-6%. (Gr. II).

Final diagnosis: Oligoastrocytoma: Grade II

Source: NCI Genomic Data Commons file e5310371-3310-4c93-99fd-c0c3138af055 (TCGA-P5-A737.3DD50AE3-0357-4D02-9AAD-589B5D87DFF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).